Somatic mutation profile of tumor specimen MP2PRT-PARLUL-TMP1-A (aliquot MP2PRT-PARLUL-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PARLUL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,543 days).
Specimen MP2PRT-PARLUL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99561805-d0a5-4bcc-8485-f18751706d91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARLUL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARLUL-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3b8acee-5c65-4545-a105-e7514f1452a4

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 3, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 43/505 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ADGRV1 | c.16249G>A p.V5417I | Missense Mutation (SNP) | VAF 65/302 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs375876245; called by muse, mutect2, varscan2
- GLRA4 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 56/754 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768567167, COSV65457234; called by muse, mutect2
- GPHB5 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 58/545 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs577763784, COSV58487535; called by muse, mutect2
- IGHV3-66 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.099); catalogued as rs377538322; called by muse, varscan2
- KCNT1 | c.424G>A p.E142K (on ENST00000488444; = p.E161K on NM_020822.3) | Missense Mutation (SNP) | VAF 27/509 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs770108075, COSV99705558; called by muse, mutect2
- KPRP | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 168/402 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.047); catalogued as rs763479865, COSV64223128; called by muse, mutect2, varscan2
- PC | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 60/798 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs759168945, COSV63081815; called by muse, mutect2
- PGM1 | c.1277C>T p.T426I | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1400763909; called by muse, mutect2
- SEMG1 | c.1327G>T p.D443Y | Missense Mutation (SNP) | VAF 25/423 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV99725120; called by muse, mutect2
- SLC44A1 | c.1069C>T p.L357F | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1275094043; called by muse, mutect2, varscan2
- TIE1 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 49/774 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.693); catalogued as COSV100992015; called by muse, mutect2
- ARHGAP9 | c.641A>G p.Q214R | Missense Mutation (SNP) | VAF 53/572 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- ARSF | c.500T>C p.F167S | Missense Mutation (SNP) | VAF 136/588 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- EPN2 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 157/418 reads (38%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FLNB | c.65_76delinsCCCCCCCCCCCTCGGGCTGGTGG p.F22Sfs*16 | Frame Shift Ins (INS) | VAF 38/367 reads (10%) | called by muse*, pindel
- PSG8 | c.1007G>T p.R336I | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- SLC40A1 | c.838C>A p.Q280K | Missense Mutation (SNP) | VAF 159/377 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VIL1 | c.1400A>G p.D467G | Missense Mutation (SNP) | VAF 204/453 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CCSER2 | c.2196G>A p.K732= | Silent (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- DPYSL5 | c.567C>T p.R189= | Silent (SNP) | VAF 118/373 reads (32%) | catalogued as rs375356199; called by muse, varscan2
- TRIM27 | c.417C>T p.F139= | Silent (SNP) | VAF 192/471 reads (41%) | called by muse, mutect2, varscan2
- RIMS2 | c.699-4632C>G | Intron (SNP) | VAF 110/252 reads (44%) | called by muse, mutect2, varscan2
